Somatic mutation profile of tumor specimen TCGA-59-2352-01A (aliquot TCGA-59-2352-01A-01W-0799-08) from TCGA case TCGA-59-2352, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3.
Specimen TCGA-59-2352-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bed0cbcb-7285-4d43-8cba-950c5cfb7aa0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-59-2352-10A (Blood Derived Normal), aliquot TCGA-59-2352-10A-01W-0800-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d01a3664-7ba0-457c-88ce-a70a30244c79

The open-access MAF lists 99 somatic variants for this specimen: 73 protein-altering or splice-affecting, 22 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 67, Silent 22, Nonsense Mutation 2, Frame Shift Del 2, RNA 2, 3'Flank 1, Splice Site 1, Intron 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.797G>T p.G266V | Missense Mutation (SNP) | VAF 53/66 reads (80%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs193920774, CM1414506, COSV52664019, COSV52666760, COSV53585299; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- A1CF | c.664G>C p.V222L | Missense Mutation (SNP) | VAF 45/239 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.102); catalogued as COSV50980714; called by muse, mutect2, varscan2
- ACO2 | c.1831G>A p.D611N | Missense Mutation (SNP) | VAF 42/138 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.197); catalogued as COSV53443857; called by muse, mutect2, varscan2
- ACRBP | c.236A>G p.Y79C | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.819); catalogued as COSV99976185; called by muse, mutect2
- ADD3 | c.782C>T p.A261V | Missense Mutation (SNP) | VAF 32/247 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); catalogued as COSV53323750; called by muse, mutect2, varscan2
- ADGRB3 | c.1982G>T p.W661L | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101000151, COSV65404877; called by muse, mutect2, varscan2
- ADGRG3 | c.1143G>T p.K381N | Missense Mutation (SNP) | VAF 53/73 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59651728; called by muse, mutect2, varscan2
- ATP13A2 | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.034); catalogued as rs1323958366, COSV58701713; called by muse, mutect2, varscan2
- C1orf116 | c.706T>C p.S236P | Missense Mutation (SNP) | VAF 228/468 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63944317; called by muse, mutect2, varscan2
- C6orf58 | c.64A>C p.T22P | Missense Mutation (SNP) | VAF 59/196 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.011); catalogued as COSV100314948; called by muse, mutect2, varscan2
- CCDC30 | c.2008C>T p.R670C (on ENST00000340612; = p.R627C on NM_001080850.3) | Missense Mutation (SNP) | VAF 39/237 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.014); catalogued as rs756061016, COSV59604538; called by muse, mutect2, varscan2
- CCDC6 | c.676G>T p.A226S | Missense Mutation (SNP) | VAF 42/179 reads (23%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.46); catalogued as COSV54057901; called by muse, mutect2, varscan2
- CCNI | c.599C>G p.S200C | Missense Mutation (SNP) | VAF 35/153 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV52960264; called by muse, mutect2, varscan2
- CD200R1 | c.163A>G p.T55A (on ENST00000471858 / NM_170780.3; = p.T78A on NM_138806.4) | Missense Mutation (SNP) | VAF 178/743 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as rs1218405044, COSV55601954; called by muse, mutect2, varscan2
- CHML | c.1025C>A p.S342* | Nonsense Mutation (SNP) | VAF 23/164 reads (14%) | catalogued as COSV59365656; called by muse, mutect2, varscan2
- COL16A1 | c.3832C>T p.P1278S | Missense Mutation (SNP) | VAF 45/102 reads (44%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV54709682; called by muse, mutect2, varscan2
- COL5A3 | c.3469G>A p.G1157R | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758281459, COSV53413987; called by muse, mutect2
- CSMD3 | c.566T>C p.L189S | Missense Mutation (SNP) | VAF 51/238 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV52232962; called by muse, mutect2, varscan2
- CUL9 | c.5107C>T p.R1703C | Missense Mutation (SNP) | VAF 121/598 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199801229, COSV52730877; called by muse, varscan2
- CUL9 | c.5179G>T p.A1727S | Missense Mutation (SNP) | VAF 84/570 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.033); catalogued as COSV52730411, COSV52730887; called by muse, varscan2
- DCUN1D1 | c.303T>G p.S101R | Missense Mutation (SNP) | VAF 30/148 reads (20%) | SIFT tolerated (0.53); PolyPhen benign (0.374); catalogued as COSV53045115; called by muse, mutect2, varscan2
- DHX29 | c.298G>C p.G100R | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.084); catalogued as COSV52419405; called by muse, mutect2, varscan2
- DLG4 | c.1034G>A p.G345D (on ENST00000399506 / NM_001321075.3; = p.G388D on NM_001365.4) | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1408572008, COSV57240029; called by mutect2, varscan2
- FAM114A1 | c.613T>G p.S205A | Missense Mutation (SNP) | VAF 26/129 reads (20%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.763); catalogued as COSV62673614; called by muse, mutect2, varscan2
- FANCM | c.1064G>C p.G355A | Missense Mutation (SNP) | VAF 33/261 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.324); catalogued as COSV99951228; called by muse, mutect2, varscan2
- GBP3 | c.787C>T p.Q263* | Nonsense Mutation (SNP) | VAF 105/428 reads (25%) | catalogued as COSV52519034; called by muse, mutect2, varscan2
- GLI2 | c.1354G>C p.E452Q (on ENST00000361492 / NM_001374353.1; = p.E469Q on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/132 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV58045709; called by muse, mutect2, varscan2
- GRIK3 | c.284C>G p.T95S | Missense Mutation (SNP) | VAF 89/373 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV66142409; called by muse, mutect2, varscan2
- HSD17B11 | c.695G>T p.S232I | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.746); catalogued as COSV64154765; called by muse, mutect2, varscan2
- KMT5A | c.1043C>A p.P348Q | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100389540; called by muse, mutect2, varscan2
- KRT25 | c.1111G>A p.D371N | Missense Mutation (SNP) | VAF 131/512 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.077); catalogued as COSV100380009, COSV56445584; called by muse, mutect2, varscan2
- LIN7A | c.548A>G p.K183R | Missense Mutation (SNP) | VAF 62/368 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.06); catalogued as rs746961716, COSV54023941; called by muse, mutect2, varscan2
- LMNTD1 | c.854G>C p.W285S | Missense Mutation (SNP) | VAF 61/701 reads (9%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.63); catalogued as COSV51446109, COSV51448527; called by muse, mutect2
- LRRC47 | c.1518G>C p.M506I | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV65562889; called by muse, mutect2
- MACF1 | c.13772C>T p.P4591L (on ENST00000372915; = p.P2524L on NM_012090.5) | Missense Mutation (SNP) | VAF 18/267 reads (7%) | catalogued as rs775377818, COSV99245402; called by muse, mutect2
- MIA2 | c.1851T>A p.N617K | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV54484629; called by muse, mutect2, varscan2
- MIB1 | c.151G>C p.V51L | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV55092272; called by muse, mutect2, varscan2
- MYO1C | c.2842G>A p.V948I (on ENST00000648651 / NM_001080779.2; = p.V913I on NM_033375.5) | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.014); catalogued as rs764512419, COSV100704441; called by muse, mutect2, varscan2
- NAA11 | c.590C>T p.P197L | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs761201577, COSV54515009; called by muse, mutect2, varscan2
- NCAM2 | c.2226del p.S744Vfs*18 | Frame Shift Del (DEL) | VAF 56/299 reads (19%) | catalogued as COSV99526432; called by mutect2, pindel, varscan2
- NEXMIF | c.4057A>G p.I1353V | Missense Mutation (SNP) | VAF 38/166 reads (23%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); catalogued as COSV50048639; called by muse, mutect2, varscan2
- NPPB | c.295C>T p.R99W | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.153); catalogued as rs749132971, COSV64687254; called by muse, mutect2, varscan2
- OCRL | c.2587C>T p.L863F | Missense Mutation (SNP) | VAF 404/607 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV63981286; called by muse, mutect2, varscan2
- OR2M5 | c.103T>A p.F35I | Missense Mutation (SNP) | VAF 340/1531 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.486); catalogued as rs767045918, COSV63546609; called by muse, mutect2, varscan2
- PCDH15 | c.5363C>G p.T1788R | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious, low confidence (0); catalogued as COSV64708374; called by muse, mutect2, varscan2
- PCDHB13 | c.2258T>C p.V753A | Missense Mutation (SNP) | VAF 58/248 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.216); catalogued as COSV99507454; called by muse, mutect2, varscan2
- PI4K2B | c.914G>C p.R305T | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV53512064; called by muse, mutect2, varscan2
- PKD2L1 | c.2006G>C p.R669T | Missense Mutation (SNP) | VAF 49/217 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.066); catalogued as COSV58396954; called by muse, mutect2, varscan2
- PLAC9 | c.202A>G p.K68E | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.345); catalogued as COSV64840614; called by muse, mutect2, varscan2
- PRDM1 | c.1084C>T p.P362S | Missense Mutation (SNP) | VAF 29/143 reads (20%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.964); catalogued as COSV100958646, COSV64845771; called by muse, mutect2, varscan2
- PTPRB | c.257G>A p.R86H | Missense Mutation (SNP) | VAF 37/115 reads (32%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs758650156, COSV51730015; called by muse, mutect2, varscan2
- REXO5 | c.591G>C p.M197I | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.186); catalogued as COSV54473200; called by muse, mutect2, varscan2
- RTTN | c.4091C>G p.T1364S | Missense Mutation (SNP) | VAF 54/284 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55347960; called by muse, mutect2, varscan2
- SCAMP3 | c.73G>C p.A25P | Missense Mutation (SNP) | VAF 69/152 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as rs889235851, COSV56946261; called by muse, mutect2, varscan2
- SETD6 | c.545C>T p.A182V (on ENST00000219315 / NM_001160305.4; = p.A158V on NM_024860.3) | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as rs944285867; called by muse, mutect2
- SFMBT2 | c.164C>T p.A55V | Missense Mutation (SNP) | VAF 39/300 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.101); catalogued as COSV62812323; called by muse, mutect2, varscan2
- SIX1 | c.798G>T p.Q266H | Missense Mutation (SNP) | VAF 15/142 reads (11%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.439); catalogued as COSV55960404, COSV55960728; called by muse, mutect2, varscan2
- SLC10A1 | c.782A>C p.Q261P | Missense Mutation (SNP) | VAF 24/209 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV53683057, COSV53684370; called by muse, mutect2, varscan2
- SLC5A3 | c.1598C>A p.T533K | Missense Mutation (SNP) | VAF 27/142 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62971245; called by muse, mutect2, varscan2
- SLC6A11 | c.796C>G p.L266V | Missense Mutation (SNP) | VAF 116/1790 reads (6%) | SIFT tolerated (0.91); PolyPhen benign (0.021); catalogued as COSV99594661; called by muse, mutect2
- SLF1 | c.2108C>G p.S703C | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV54371437; called by muse, mutect2, varscan2
- TMEM132B | c.2789G>C p.R930T | Missense Mutation (SNP) | VAF 70/394 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as COSV54759118, COSV54769688, COSV54770449; called by muse, mutect2, varscan2
- TNRC6B | c.1249C>G p.R417G | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.51); PolyPhen benign (0.334); catalogued as rs201621003, COSV57294459; called by muse, mutect2, varscan2
- TP53BP1 | c.3470T>G p.M1157R | Missense Mutation (SNP) | VAF 72/309 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.04); catalogued as COSV55504265; called by muse, mutect2, varscan2
- TRIM24 | c.732del p.D245Tfs*5 | Frame Shift Del (DEL) | VAF 37/179 reads (21%) | catalogued as COSV58969614; called by mutect2, pindel, varscan2
- USP6 | c.1751G>T p.C584F | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.571); catalogued as COSV100004332; called by muse, mutect2
- ZEB1 | c.923C>T p.T308I | Missense Mutation (SNP) | VAF 66/540 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.232); catalogued as COSV58048480; called by muse, mutect2, varscan2
- ZEB2 | c.677T>C p.L226P | Missense Mutation (SNP) | VAF 56/248 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57960416; called by muse, mutect2, varscan2
- ZNF468 | c.1201C>G p.H401D | Missense Mutation (SNP) | VAF 53/453 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54695645; called by muse, mutect2, varscan2
- ZNF816-ZNF321P | c.293T>A p.I98N | Missense Mutation (SNP) | VAF 139/324 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); catalogued as COSV58349620; called by muse, mutect2, varscan2
- CYP2S1 | c.671_673del p.S224del | In Frame Del (DEL) | VAF 185/1148 reads (16%) | called by mutect2, pindel, varscan2
- IGKV1D-43 | c.323A>G p.Y108C | Missense Mutation (SNP) | VAF 62/630 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PHKG2 | c.393-2del p.X131_splice | Splice Site (DEL) | VAF 7/41 reads (17%) | called by mutect2, pindel, varscan2
- ALPK1 | c.2292G>A p.E764= | Silent (SNP) | VAF 27/127 reads (21%) | catalogued as rs773713033, COSV51587660; called by muse, mutect2, varscan2
- ARHGAP18 | c.1734G>C p.V578= | Silent (SNP) | VAF 52/280 reads (19%) | catalogued as COSV63765119; called by muse, mutect2, varscan2
- ARHGAP5 | c.3031A>C p.R1011= | Silent (SNP) | VAF 86/485 reads (18%) | catalogued as COSV61537378; called by muse, mutect2, varscan2
- CDH9 | c.24A>G p.P8= | Silent (SNP) | VAF 20/179 reads (11%) | catalogued as rs773597398, COSV50327776; called by muse, mutect2, varscan2
- CDHR5 | c.570C>T p.P190= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV62763443; called by muse, mutect2, varscan2
- CDON | c.1635T>G p.G545= | Silent (SNP) | VAF 64/284 reads (23%) | catalogued as COSV54999775; called by muse, mutect2, varscan2
- CLEC14A | c.906C>G p.P302= | Silent (SNP) | VAF 34/282 reads (12%) | catalogued as COSV60563293; called by muse, mutect2, varscan2
- EPM2AIP1 | c.12G>C p.T4= | Silent (SNP) | VAF 28/183 reads (15%) | catalogued as COSV51620563, COSV99212359; called by muse, mutect2, varscan2
- IL20RA | c.1383G>A p.A461= | Silent (SNP) | VAF 40/235 reads (17%) | catalogued as rs772185815, COSV57359140; called by muse, mutect2, varscan2
- KLHL9 | c.1230T>C p.A410= | Silent (SNP) | VAF 46/223 reads (21%) | catalogued as COSV62921975; called by muse, mutect2, varscan2
- LRRC23 | c.831G>T p.L277= | Silent (SNP) | VAF 24/267 reads (9%) | catalogued as COSV99145241; called by muse, mutect2
- LRRC8B | c.108G>T p.L36= | Silent (SNP) | VAF 60/496 reads (12%) | catalogued as COSV58375902; called by muse, mutect2, varscan2
- PCDHA2 | c.1644C>T p.N548= | Silent (SNP) | VAF 31/146 reads (21%) | catalogued as COSV65367787; called by muse, mutect2, varscan2
- PCDHB13 | c.2259G>T p.V753= | Silent (SNP) | VAF 56/244 reads (23%) | catalogued as COSV99507457; called by muse, mutect2, varscan2
- PPP1R13B | c.792G>A p.A264= | Silent (SNP) | VAF 50/222 reads (23%) | catalogued as rs368023622; called by muse, mutect2, varscan2
- RARS1 | c.978G>A p.L326= | Silent (SNP) | VAF 25/123 reads (20%) | catalogued as COSV51564643, COSV99199073; called by muse, mutect2, varscan2
- RNASE1 | c.30C>T p.L10= | Silent (SNP) | VAF 4/52 reads (8%) | catalogued as rs1186465673, COSV100564505; called by muse, mutect2
- SETD5 | c.3072A>G p.G1024= | Silent (SNP) | VAF 17/98 reads (17%) | catalogued as COSV56713907; called by muse, mutect2, varscan2
- TEKT5 | c.1434C>T p.T478= | Silent (SNP) | VAF 53/215 reads (25%) | catalogued as COSV51590064; called by muse, mutect2, varscan2
- TGFBI | c.987C>A p.T329= | Silent (SNP) | VAF 31/118 reads (26%) | catalogued as rs761165775, COSV100526584, COSV59354162; called by muse, mutect2, varscan2
- TGM4 | c.1881G>T p.L627= | Silent (SNP) | VAF 72/370 reads (19%) | catalogued as COSV56094919; called by muse, mutect2, varscan2
- ZNF594 | c.1251A>T p.S417= | Silent (SNP) | VAF 94/555 reads (17%) | catalogued as COSV68385752; called by muse, mutect2, varscan2
- AC024940.1 | n.3791T>G | RNA (SNP) | VAF 18/204 reads (9%) | called by muse, mutect2
- GOSR2 | c.282+2898C>T | Intron (SNP) | VAF 83/334 reads (25%) | catalogued as rs753166413, COSV56663200; ClinVar: likely benign; called by muse, mutect2, varscan2
- MIR876 | n.54G>A | RNA (SNP) | VAF 22/85 reads (26%) | called by muse, mutect2, varscan2
- OR52A4P | chr11:5120733 G>C | 3'Flank (SNP) | VAF 55/317 reads (17%) | called by muse, mutect2, varscan2
